Gene-level copy-number profile of tumor specimen TCGA-CG-5723-01A from TCGA case TCGA-CG-5723, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-CG-5723-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.342adba1-c740-4845-a7d3-ad322eb590bb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-5723-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7ba84475-7a65-4b3a-822e-cce35890d89d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 3,957; copy number 2: 55,335; copy number 3: 526.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-5723-01A-11D-1599-01): tumor purity 0.47, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,442,060–9,803,784, 2 genes: RN7SL5P, AL513422.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,571. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
